Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A495, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A495-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

ICD-O-3

Carcinoma, hepatocellular, NOS
8170/3

Sites liver, C22.0

9-7-12

RD

DIAGNOSIS

LIVER, SEGMENTS 5 AND 6, RESECTION:

1. Hepatocellular carcinoma, featuring:

- a. Size: 4.5 cm with three satellite lesions ranging from 0.5 to 1 cm in diameter
- b. Grade 2 (of 3), see comment
- c. Vascular invasion: Absent
- d. Margins: Negative by 0.3 cm
- e. See staging parameters

2. Background liver shows chronic hepatitis C, featuring:

- a. Mild necroinflammatory activity (grade 1-2 of 4)
- b. Periportal fibrosis (stage 2 of 4)

B) GALLBLADDER, CHOLECYSTECTOMY:

- 1. Chronic cholecystitis
- 2. Negative for neoplasm

COMMENT

A) The largest satellite lesion has histologic grade 2 (of 3) while the primary (largest) lesion and the smaller satellite lesions demonstrate histologic grade 1.

***** LIVER HEPATOCELLULAR CANCER STAGING PARAMETERS*****

Case number: [REDACTED]

Patient name: [REDACTED]

Final TNM: pT1NXM0

2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Segmentectomies

Segments 5 & 6

TUMOR TYPE

Single with satellites

Tumor #2 is by definition a satellite of tumor #1 (same segment, <2 cm apart, less than 50% diameter or the larger lesion and <4cm in diameter). In addition the irregular nodularities noted grossly represent two smaller satellites, 0.5 cm in diameter.

TUMOR SIZE

Single tumor measuring 4.5 X 4.2 X 2.5 cm, with 3 satellite tumors measuring 0.5-1 cm

MICROSCOPIC

HISTOLOGIC TYPE

Hepatocellular carcinoma

HISTOLOGIC GRADE

[page 2 of 3]
[REDACTED]

Nuclear grade 2 of 3 (Lauwers grade)
MARGINS
Uninvolved by tumor
Distance to nearest margin is 0.3 cm
LIVER CAPSULE
No tumor present
LYMPHATIC/VASCULAR INVASION
Absent: Lymph-vascular invasion not present/Not identified
TUMOR EXTENSION
Tumor confined to liver
MITOTIC ACTIVITY
21/10 HPF
HEPATOCELLULAR PROGNOSTIC INDEX
Fair prognosis - Grade 2 without vascular invasion

PATHOLOGIC STAGING
EXTENT OF INVASION
pT1. (Solitary tumor without vascular invasion)
REGIONAL LYMPH NODES
pNX. (Cannot be assessed)
Total nodes: 0
DISTANT METASTASIS
pM0. (No distant metastasis)
PATHOLOGIC STAGE Summary
Final TNM: pT1NXM0
stage: I
** The pathologic stage presumes no distant metastasis.

PROGNOSTIC FACTORS (SITE SPECIFIC FACTORS)

CIRRHOSIS
Absent
SMALL CELL DYSPLASIA
Absent
ALPHAFETOPROTEIN (AFP)
39.4
FIBROSIS SCORE
Stage 2 of 4
HEPATITIS SEROLOGY
Hepatitis C positive

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Liver, segments 5 & 6
The specimen is received fresh from the OR labeled "segments 5 and 6" and consists a 108 gram, 10.3 x 5.5 x 4.3 cm wedge of red, pale tan liver parenchyma. The specimen displays a smooth, focally irregular capsular surface. The margin is inked blue and the tissue is serially cross-sectioned.

INTRAOPERATIVE PATHOLOGY CONSULTATION: "Margins free (0.7 cm from the smaller nodule)." is rendered by [REDACTED].

The cut surfaces display two tumors and two small ovoid irregular nodular foci.

[REDACTED]

[page 3 of 3]
[REDACTED]

Tumor #1 (4.5 x 4.2 x 2.5 cm) is located 2.2 cm from the blue-inked margin and display vaguely lobulated tan cut surfaces interspersed with thin fibrous septae. Tumor #1 abuts the capsular surface. Extension through the capsule is not seen.

Tumor #2 (1 cm in diameter) is 0.7 cm from the closest blue-inked margin and 1.3 cm from tumor #1. Tumor #2 has tan, lobulated soft cut surfaces.

The two small ovoid ill-defined nodularities each measure 0.5 cm in average diameter. The closest nodule is 0.3 cm from the blue-inked margin. The two nodules are at least 1 cm from the two tumors. No other lesions are seen on the red-tan hepatic parenchyma. Representative sections are submitted in six cassettes labeled:

- 1-2. Tumor #2 entirely submitted with closest blue-inked margin
- 3-4. Blue-inked margin closest to tumor #1 to include the two smaller irregular nodularities, entirely submitted
- 5-6. Tumor #1 with adjacent hepatic parenchyma

Note: The gross specimen was photographed. Representative tumor, paranormal and normal tissue are banked.

Note: Specimen removed from patient at [REDACTED]. Specimen placed in 10% neutral buffered formalin at [REDACTED]. Specimen fixed in formalin for a minimum of 6 hours, and not longer than 48 hours.

[REDACTED]

B) SOURCE: Gallbladder

Labeled "gallbladder" is an 8.5 x 3.3 x 2 cm intact-appearing gallbladder. The serosa is tan-maroon and focally roughened. The wall is 0.2-0.3 cm thick. The mucosa is soft glistening, mottled green-tan. Found within the lumen is watery yellow-green bile. After filtering and careful examination of the lumen and specimen container contents, no discrete choleliths are identified. No lesions or masses are seen. Representative sections including the apparent cystic duct margin (inked blue) are submitted in a single cassette.

This case is accessioned in [REDACTED]

Gross dictation by: [REDACTED]

MICROSCOPIC

A) The background livers shows changes classical for hepatitis C including moderate lymphoid aggregates and significant interface necroinflammatory activity. There is also mild zone 1 steatosis without steatohepatitis. There is no evidence of septal fibrosis or cirrhosis.

B) The microscopic appearance substantiates the diagnosis.

Dictation by: [REDACTED] transcribed by: [REDACTED]

Interpreted at [REDACTED]

COLLECTED:

ACCESSIONED:

SIGNED:

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]

Lab and Collection

Case is (circled)		

8/10/12

Source: NCI Genomic Data Commons file 28da961f-cd56-494d-b119-ac1ffea25bb6 (TCGA-FV-A495.99D80D8A-88F7-445D-9B87-9B4B96C3C010.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).